Somatic mutation profile of tumor specimen TCGA-49-4510-01A (aliquot TCGA-49-4510-01A-01D-1265-08) from TCGA case TCGA-49-4510, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 51.4 years (18,762 days).
Specimen TCGA-49-4510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 285301af-26df-4d59-991a-5933938f9a38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-4510-11A (Solid Tissue Normal), aliquot TCGA-49-4510-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0da50c40-ffa7-4bfc-8e87-02d456940500

The open-access MAF lists 48 somatic variants for this specimen: 40 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 7, Nonsense Mutation 4, Intron 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 15/30 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.2263G>T p.G755* | Nonsense Mutation (SNP) | VAF 69/185 reads (37%) | catalogued as COSV61261028; called by muse, mutect2, varscan2
- ATM | c.9043G>T p.E3015* | Nonsense Mutation (SNP) | VAF 48/81 reads (59%) | catalogued as COSV53739362; called by muse, mutect2, varscan2
- BAP1 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs910211860, COSV56230719; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICD1 | c.2601C>G p.S867R | Missense Mutation (SNP) | VAF 99/381 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV55674570, COSV55677986; called by muse, mutect2, varscan2
- CAMK4 | c.718C>G p.P240A | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56669039; called by muse, mutect2
- CARTPT | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57114941; called by muse, mutect2, varscan2
- CASR | c.1504G>A p.A502T (on ENST00000490131; = p.A579T on NM_000388.4) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV56136721; called by muse, mutect2, varscan2
- CFAP57 | c.863T>C p.I288T | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs750661261, COSV65264265; called by muse, mutect2, varscan2
- CKMT2 | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV99562381; called by muse, mutect2, varscan2
- CLEC9A | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100872812; called by muse, mutect2, varscan2
- CNTLN | c.1066C>G p.Q356E | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT tolerated (0.54); PolyPhen benign (0.12); catalogued as COSV52075178; called by muse, mutect2, varscan2
- CPB1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 61/92 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370907426; called by muse, mutect2, varscan2
- EIF4E | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as COSV55187021; called by muse, mutect2, varscan2
- EPHB6 | c.1708G>T p.G570C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63891356, COSV63891416; called by muse, mutect2, varscan2
- EXPH5 | c.2969A>G p.E990G | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV56201225; called by muse, mutect2, varscan2
- FBXL7 | c.156C>A p.S52R | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV61644778, COSV61651089; called by muse, mutect2, varscan2
- FMO4 | c.946A>T p.T316S | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.533); catalogued as COSV100882107, COSV63000948; called by muse, mutect2, varscan2
- GABRA6 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 13/148 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV50879956; called by muse, mutect2
- GNAS | c.465C>G p.S155R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as COSV58333092; called by mutect2, varscan2
- HECW1 | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV67827359; called by muse, mutect2, varscan2
- KDM5A | c.1528G>T p.A510S | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV66991892; called by muse, mutect2, varscan2
- LARP1B | c.1415C>G p.S472C | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as COSV52796632; called by muse, mutect2, varscan2
- MAB21L2 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.869); catalogued as COSV100462152; called by muse, mutect2, varscan2
- MYH1 | c.1470G>T p.Q490H | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56846949; called by muse, mutect2, varscan2
- OR13F1 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1564201756, COSV58250716; called by muse, mutect2, varscan2
- OSBPL6 | c.1622T>C p.I541T | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0.038); catalogued as COSV51915683; called by muse, mutect2, varscan2
- OXCT1 | c.901G>T p.V301L | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV52169893, COSV52172286; called by muse, mutect2, varscan2
- PCDHA6 | c.321G>T p.E107D | Missense Mutation (SNP) | VAF 102/306 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); catalogued as COSV65351520; called by muse, mutect2, varscan2
- PEX3 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 13/173 reads (8%) | catalogued as COSV62568427; called by muse, mutect2
- REG1B | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59305156; called by muse, mutect2, varscan2
- RFX7 | c.2183G>T p.G728V (on ENST00000559447 / NM_001368074.1; = p.G825V on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV57962481; called by muse, mutect2, varscan2
- SENP7 | c.2684A>G p.D895G | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV58610988; called by muse, mutect2
- SLAMF6 | c.673A>C p.K225Q | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.047); catalogued as COSV63586936; called by muse, mutect2
- TAZ | c.637T>C p.W213R | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54796241; called by muse, mutect2
- TC2N | c.419T>A p.L140* | Nonsense Mutation (SNP) | VAF 79/121 reads (65%) | catalogued as COSV100563042, COSV61746780; called by muse, mutect2, varscan2
- TRIM23 | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.98); PolyPhen benign (0.334); catalogued as rs1422426045, COSV99139992; called by muse, mutect2, varscan2
- ZFPM2 | c.1483G>T p.G495C | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65873188; called by muse, mutect2, varscan2
- ZNF680 | c.743A>G p.N248S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.559); catalogued as rs149707711; called by muse, mutect2, varscan2
- RNF139 | c.1183_1200del p.V395_F400del | In Frame Del (DEL) | VAF 256/698 reads (37%) | called by mutect2, pindel, varscan2
- BBS2 | c.429T>C p.A143= | Silent (SNP) | VAF 62/219 reads (28%) | catalogued as COSV55326035; called by muse, mutect2, varscan2
- BPI | c.894G>A p.G298= (on ENST00000262865; = p.G294= on NM_001725.3) | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV53405260; called by muse, mutect2, varscan2
- CD160 | c.417A>T p.T139= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as rs781987146, COSV99353450; called by muse, mutect2, varscan2
- GLUL | c.1008C>T p.Y336= | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as COSV59382040; called by muse, mutect2
- OTUD7B | c.657A>G p.A219= | Silent (SNP) | VAF 78/193 reads (40%) | catalogued as COSV64915952; called by muse, mutect2, varscan2
- RANBP2 | c.4167A>T p.P1389= | Silent (SNP) | VAF 86/239 reads (36%) | catalogued as COSV51699832; called by muse, mutect2, varscan2
- ZNF112 | c.12C>T p.F4= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as COSV100495766; called by muse, mutect2, varscan2
- TTN | c.10360+1939A>G | Intron (SNP) | VAF 29/143 reads (20%) | catalogued as COSV60000660; called by muse, mutect2, varscan2
